Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACI, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACI-01A (Primary Tumor).

[page 1 of 3]
CLINICAL DIAGNOSIS: R/O Carcinosarcoma

Specimen : liver

Gross Photo : 1

GROSS:

1. Specimen:
Liver: 10.0 x 9.0 x 12.0 cm, fixed
2. Tumor location: left
Tumor number: one
Tumor size: 5.5 x 3.5 x 5.0 cm
3. Satellite nodule: no
4. Gross type
HCC: expanding nodular
5. Tumor necrosis: no
6. Hemorrhage/peliosis: no
7. Portal vein invasion: yes
8. Bile duct invasion: no
9. Others: dystrophic calcification in the fibrotic septa, central

ICD-O-3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JWS/19/14

Gross photo present.

Blocks

- T1-4, TB, tumor and surrounding liver tissue x 5
L, NB, remaining liver tissue x 2
RM, resection margin of liver x 1
A, labeled "tumor emboli" x 1

MICROSCOPIC:

1. Hepatocellular carcinoma: yes
- 1-1. Differentiation
The worst differentiation: III
The major differentiation: III
- 1-2. Histologic type: trabecular and solid
- 1-3. Cell type: hepatic
- 1-4. Fatty change: yes (30-40 %)
2. Other tumor: no
3. Fibrous capsule formation: partial
4. Capsular infiltration: yes
5. Septum formation: partial
6. Surgical resection margin invasion: no

[page 2 of 3]
7. Serosal invasion: no
8. Portal vein invasion: yes
9. Bile duct invasion: no
10. Hepatic vein invasion: no
11. Hepatic artery invasion: no
12. Microvessel invasion: no
13. Intrahepatic metastasis: no
14. Multicentric occurrence: no
15. Others: dystrophic calcification is present

Non-tumor liver pathology

1. Chronic hepatitis: yes
- 1-1. Etiology: unknown cause
- 1-2. Grade, lobular: minimal (grade I)
- 1-3. Grade, portoperiportal: minimal (grade I)
- 1-4. Stage (fibrosis): precirrhotic (stage III-IV)
2. Dysplastic nodule: no
3. Ductal epithelial dysplasia: no
4. Other liver diseases: no

SPECIAL STAIN:

Reticulum stain shows arrangement of tumor cells.

Trichrome stain shows fibrotic septum.

NOT reported. Gross:

Bile duct, smear, inflammation

Bile duct, smear, inflammation

liver,needle,hepatocellular carcinoma

Liver, ectomy, hepatocellular carcinoma, cholangiocytic differentiation, precirrhotic fibrosis
T56000, P10, M81703, cholangiocytic differentiation, precirrhotic fibrosis

DIAGNOSIS:

[page 3 of 3]
Liver, segment, left, segmentectomy:

Hepatocellular carcinoma, moderately differentiated,
with cholangiocytic differentiation (see NOTE)
Precirrhotic fibrosis

NOTE: Tumor

cholangiocytic differentiation : hepatocellular carcinoma

Suggestion :

Source: NCI Genomic Data Commons file 89266c6d-3340-42b7-b550-7e481358d3cc (TCGA-DD-AACI.54CDEB1D-8CF9-4723-9A7D-CD9DFEDFD659.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).